Gene-level copy-number profile of tumor specimen TCGA-BC-4072-01B from TCGA case TCGA-BC-4072, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.4 years (27,162 days).
Specimen TCGA-BC-4072-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.6d597369-6a96-4565-a304-85be887ba1d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-4072-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/21419f58-7161-433a-bcb2-c608a8daecfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,841; copy number 2: 45,619; copy number 3: 8,698; copy number 4: 896; copy number 5: 437; copy number 6: 70; copy number 7: 180; copy number 8: 35; copy number 10: 3; copy number 21: 36.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 761 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:78,939,850–79,357,594, 8 genes, copy number 7: MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1.
- chr7:80,662,331–80,974,724, 3 genes, copy number 6: AC073850.1, SEMA3C, AC004972.1.
- chr7:88,420,167–88,756,725, 1 gene, copy number 7 (within-gene range 2–7): AC002069.2.
- chr7:88,564,793–92,971,299, 61 genes, copy number 7–21 (broad region; genes not listed).
- chr7:94,278,680–96,322,147, 35 genes, copy number 8 (within-gene range 1–8): AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1.
- chr7:108,470,417–108,884,587, 7 genes, copy number 6: PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66.
- chr8:48,913,916–52,745,843, 38 genes, copy number 5: AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr8:89,585,872–131,317,632, 608 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
